Somatic mutation profile of tumor specimen 91b287fd-eadb-442d-abcd-20b741 (aliquot 91b287fd-eadb-442d-abcd-20b741_D6) from CPTAC case 04OV058, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC.
Specimen 91b287fd-eadb-442d-abcd-20b741: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b0f7235-0a70-4073-9020-b3dd6b09baa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen d035cd3d-9ecd-4c59-a1ca-a247fe (Blood Derived Normal), aliquot d035cd3d-9ecd-4c59-a1ca-a247fe_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f8852f3-b9e0-4e15-a3d2-7bec9d08f601

The open-access MAF lists 50 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 12, Intron 5, RNA 3, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN2A | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 94/273 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121917748, CM012186; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.808T>C p.F270L | Missense Mutation (SNP) | VAF 213/318 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1057519988, CM161002, COSV52691720, COSV52697968, COSV52744290; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.1655C>T p.T552M (on ENST00000404938 / NM_001163941.2; = p.T107M on NM_178559.6) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs201692652, COSV51706504; called by muse, mutect2, varscan2
- ATXN10 | c.647+2dup p.X216_splice | Splice Site (INS) | VAF 42/95 reads (44%) | catalogued as rs752911521; called by mutect2, pindel, varscan2
- ATXN7L2 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs759870447; called by muse, mutect2, varscan2
- BAZ2A | c.4948C>T p.R1650W | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751912640; called by muse, mutect2, varscan2
- KIF21A | c.2176C>T p.Q726* (on ENST00000361418 / NM_001378440.1; = p.Q713* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 53/185 reads (29%) | catalogued as COSV62771594; called by muse, mutect2, varscan2
- LMNTD2 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as rs758138143; called by muse, mutect2, varscan2
- LRP12 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs754942859, COSV99408550; called by muse, mutect2, varscan2
- MARK4 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99488157; called by muse, mutect2, varscan2
- PIGZ | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 110/212 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.102); catalogued as rs766979358, COSV99433835; called by muse, mutect2, varscan2
- UGT2B28 | c.1474G>C p.D492H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1383780916; called by muse, mutect2, varscan2
- ZNF184 | c.123A>C p.E41D | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99279614; called by muse, mutect2, varscan2
- ARHGAP35 | c.3403G>C p.D1135H | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- B3GNT3 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 88/141 reads (62%) | SIFT tolerated (0.28); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- EIF4EBP3 | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- FSIP2 | c.6998G>C p.R2333P | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- HPS4 | c.1616T>C p.V539A | Missense Mutation (SNP) | VAF 248/437 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- INTS6L | c.1448G>T p.R483I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- L1TD1 | c.2410A>G p.R804G | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MCEMP1 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- MUC12 | c.10291A>C p.S3431R (on ENST00000379442; = p.S3288R on NM_001164462.1) | Missense Mutation (SNP) | VAF 130/2367 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.316); called by muse, mutect2
- PCDH11X | c.1942G>T p.G648C | Missense Mutation (SNP) | VAF 228/622 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PTPRZ1 | c.5937+1G>A p.X1979_splice | Splice Site (SNP) | VAF 63/249 reads (25%) | called by muse, mutect2, varscan2
- SRP54 | c.1302G>T p.M434I | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- THBD | c.915del p.Y306Tfs*76 | Frame Shift Del (DEL) | VAF 176/546 reads (32%) | called by mutect2, varscan2
- TMTC4 | c.739dup p.I247Nfs*8 (on ENST00000376234 / NM_001350577.2; = p.I266Nfs*8 on NM_032813.5 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 19/104 reads (18%) | called by mutect2, pindel, varscan2
- TRIT1 | c.1251A>T p.K417N | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- USP24 | c.6964C>T p.Q2322* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- ZNF865 | c.1984G>C p.G662R | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ARHGAP35 | c.2253C>T p.I751= | Silent (SNP) | VAF 247/432 reads (57%) | called by muse, mutect2, varscan2
- CCDC136 | c.2925C>T p.V975= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as rs772635818; called by muse, mutect2, varscan2
- GABRB3 | c.1233G>A p.G411= | Silent (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- LIMA1 | c.930C>T p.P310= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV57964398; called by muse, mutect2, varscan2
- MYO9B | c.63C>A p.I21= | Silent (SNP) | VAF 196/535 reads (37%) | catalogued as COSV101261536; called by muse, mutect2, varscan2
- OR4S2 | c.759T>A p.T253= | Silent (SNP) | VAF 79/199 reads (40%) | called by muse, mutect2, varscan2
- PLCB1 | c.2961A>G p.S987= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs1380354498; called by muse, mutect2, varscan2
- RBBP6 | c.4989G>A p.K1663= | Silent (SNP) | VAF 25/47 reads (53%) | called by mutect2, varscan2
- SIGLEC12 | c.1347G>A p.Q449= (on ENST00000291707 / NM_053003.4; = p.Q331= on NM_033329.2) | Silent (SNP) | VAF 141/267 reads (53%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.975G>C p.S325= (on ENST00000291707 / NM_053003.4; = p.S207= on NM_033329.2) | Silent (SNP) | VAF 34/70 reads (49%) | catalogued as COSV52462594; called by muse, mutect2
- SKIV2L | c.894C>T p.R298= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs759458563; called by muse, mutect2, varscan2
- WDR62 | c.3990C>T p.S1330= | Silent (SNP) | VAF 78/421 reads (19%) | catalogued as rs778940951; called by muse, mutect2, varscan2
- AC073107.1 | n.1382G>C | RNA (SNP) | VAF 8/54 reads (15%) | catalogued as rs782619118; called by mutect2, varscan2
- APOB | c.2436+75C>T | Intron (SNP) | VAF 32/98 reads (33%) | catalogued as rs756356031; called by muse, mutect2, varscan2
- C3orf35 | n.1451G>T | RNA (SNP) | VAF 93/232 reads (40%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.138G>T | RNA (SNP) | VAF 75/258 reads (29%) | called by muse, mutect2, varscan2
- MBP | c.750+351G>A | Intron (SNP) | VAF 47/98 reads (48%) | catalogued as rs936792104; called by muse, mutect2, varscan2
- OBSCN | c.18662-2782C>G | Intron (SNP) | VAF 146/428 reads (34%) | called by muse, mutect2, varscan2
- PLXND1 | c.4994-327C>T | Intron (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- ZCCHC7 | c.610+59793C>G | Intron (SNP) | VAF 10/32 reads (31%) | catalogued as rs977242532; called by muse, mutect2, varscan2
